Somatic mutation profile of tumor specimen ALCH-AE81-TTP1-A (aliquot ALCH-AE81-TTP1-A-5-0-D-A596-36) from ALCHEMIST case ALCH-AE81, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.1 years (21,599 days).
Specimen ALCH-AE81-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00dcc401-de2c-4dd6-bad5-27472c836bd4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AE81-NB1-A (Blood Derived Normal), aliquot ALCH-AE81-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ae5aa07-3980-471d-a7cb-02a014737423

The open-access MAF lists 222 somatic variants for this specimen: 148 protein-altering or splice-affecting, 47 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 47, Intron 15, Nonsense Mutation 14, RNA 6, Frame Shift Del 5, 3'UTR 4, Splice Site 3, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 71/487 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAMTS18 | c.2447G>T p.G816V | Missense Mutation (SNP) | VAF 116/851 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51411130, COSV51424470; called by muse, mutect2, varscan2
- AHNAK2 | c.6886G>T p.D2296Y | Missense Mutation (SNP) | VAF 86/808 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs771785257; called by muse, mutect2
- AMER3 | c.1298C>T p.P433L | Missense Mutation (SNP) | VAF 38/384 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs1284318417, COSV58467018; called by muse, mutect2
- AMFR | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.283); catalogued as rs745966114, COSV51921033; called by muse, varscan2
- AMTN | c.163C>A p.P55T | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV59488991; called by muse, mutect2
- ARID1A | c.1699C>T p.Q567* | Nonsense Mutation (SNP) | VAF 70/752 reads (9%) | catalogued as COSV61374611; called by muse, mutect2
- CBLN3 | c.70C>T p.L24F | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs773414234, COSV99250186; called by muse, mutect2, varscan2
- CCDC80 | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 55/427 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs776703387; called by muse, mutect2, varscan2
- CHAT | c.2158G>T p.D720Y | Missense Mutation (SNP) | VAF 81/768 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV60332070; called by muse, mutect2, varscan2
- COL4A5 | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 36/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM145034, COSV60358492, COSV60359963; called by muse, mutect2
- CYP7B1 | c.1295G>T p.G432V | Missense Mutation (SNP) | VAF 19/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59586606; called by muse, mutect2, varscan2
- EPHA4 | c.2522A>G p.Y841C | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99915712; called by muse, mutect2
- ERICH3 | c.3965G>T p.G1322V | Missense Mutation (SNP) | VAF 71/669 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as COSV58604712; called by muse, mutect2, varscan2
- ERMP1 | c.1874C>A p.S625Y | Missense Mutation (SNP) | VAF 43/279 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.344); catalogued as rs750745938; called by muse, mutect2, varscan2
- F11 | c.1301A>G p.Y434C | Missense Mutation (SNP) | VAF 61/575 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as rs200594686; called by muse, mutect2, varscan2
- FRAS1 | c.10268C>T p.P3423L | Missense Mutation (SNP) | VAF 74/718 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs891439423, COSV53629620; called by muse, mutect2, varscan2
- GHDC | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201121685, COSV100054874; called by muse, mutect2, varscan2
- GOLGA4 | c.3352A>G p.K1118E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs368710196; called by mutect2, varscan2
- GRIA3 | c.396C>A p.D132E | Missense Mutation (SNP) | VAF 42/421 reads (10%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); catalogued as COSV99989640; called by muse, mutect2, varscan2
- IL21R | c.178G>T p.D60Y | Missense Mutation (SNP) | VAF 60/536 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV61968883; called by muse, mutect2, varscan2
- KCTD15 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 36/324 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.457); catalogued as rs752927860, COSV52292816; called by muse, mutect2, varscan2
- KIAA1549 | c.1983G>T p.Q661H | Missense Mutation (SNP) | VAF 32/351 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.635); catalogued as COSV54327699; called by muse, mutect2
- KLRC3 | c.545A>G p.H182R | Missense Mutation (SNP) | VAF 29/192 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1298220010; called by muse, mutect2, varscan2
- KREMEN2 | c.1325C>T p.A442V (on ENST00000303746 / NM_172229.3; = p.R416W on NM_024507.4) | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.028); catalogued as COSV99233970; called by muse, mutect2
- MC2R | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 30/296 reads (10%) | catalogued as COSV59618218; called by muse, mutect2
- MEN1 | c.593C>G p.T198R | Missense Mutation (SNP) | VAF 128/742 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as CM077599; called by muse, mutect2, varscan2
- MUC2 | c.1412G>T p.S471I | Missense Mutation (SNP) | VAF 40/460 reads (9%) | SIFT tolerated (0.2); catalogued as rs1440730476; called by muse, mutect2
- OR4C15 | c.812A>T p.Y271F (on ENST00000314644; = p.Y217F on NM_001001920.2) | Missense Mutation (SNP) | VAF 62/352 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as COSV100115508; called by muse, mutect2, varscan2
- OR8I2 | c.272C>G p.S91C | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV100136261; called by muse, varscan2
- PAX7 | c.1061C>A p.A354D | Missense Mutation (SNP) | VAF 75/654 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.243); catalogued as rs1473463055; called by muse, mutect2, varscan2
- PCDHGB6 | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs560438654, COSV53892940, COSV54042439; called by muse, mutect2, varscan2
- PCLO | c.15354G>T p.W5118C | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as rs1431007074, COSV61640749; called by muse, mutect2
- PCLO | c.4816G>T p.G1606W | Missense Mutation (SNP) | VAF 28/274 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61631548; called by muse, mutect2
- PHKA2 | c.3143C>A p.T1048K | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.87); PolyPhen benign (0.006); catalogued as COSV66056871; called by muse, mutect2
- PLAAT5 | c.535G>A p.V179M | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as rs778058458, COSV100080439; called by muse, mutect2, varscan2
- POTEE | c.387G>T p.M129I | Missense Mutation (SNP) | VAF 85/838 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV58225925; called by muse, mutect2, varscan2
- PSMC6 | c.562G>A p.G188R (on ENST00000612399; = p.G174R on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV71629455; called by muse, mutect2
- RAD1 | c.344A>G p.Y115C | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs1414668636, COSV57715223; called by muse, mutect2
- RBM10 | c.1248+1del | Frame Shift Del (DEL) | VAF 60/563 reads (11%) | catalogued as COSV61312597; called by mutect2, pindel, varscan2
- RFPL4A | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 138/2895 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs1263183508, COSV101467271; called by muse, mutect2
- SHISA7 | c.1217G>C p.R406P | Missense Mutation (SNP) | VAF 26/243 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as rs1482679267; called by muse, mutect2, varscan2
- SLC12A3 | c.2443G>T p.E815* (on ENST00000563236 / NM_001126108.2; = p.E824* on NM_000339.3) | Nonsense Mutation (SNP) | VAF 47/445 reads (11%) | catalogued as COSV52633056; called by muse, mutect2, varscan2
- SMPX | c.12del p.K5Nfs*76 | Frame Shift Del (DEL) | VAF 56/560 reads (10%) | catalogued as COSV65277051; called by mutect2, varscan2
- SPAG1 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV52562004; called by muse, mutect2, varscan2
- STIM1 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 60/621 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100330499, COSV100330549, COSV56161959; called by muse, mutect2
- SYNE1 | c.7733C>G p.S2578C (on ENST00000367255 / NM_182961.4; = p.S2585C on NM_033071.3) | Missense Mutation (SNP) | VAF 23/310 reads (7%) | SIFT tolerated (0.99); PolyPhen benign (0.006); catalogued as COSV54912639, COSV54955351; called by muse, mutect2
- TMPRSS11B | c.206C>A p.A69D | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV60291060; called by muse, mutect2, varscan2
- WNK4 | c.704G>A p.R235H | Missense Mutation (SNP) | VAF 47/571 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs893450739, COSV99519266; called by muse, mutect2
- WNT2 | c.308G>A p.R103Q | Missense Mutation (SNP) | VAF 40/278 reads (14%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.948); catalogued as rs780168813, COSV55410223; called by muse, mutect2
- ZCCHC8 | c.1140+1G>T p.X380_splice | Splice Site (SNP) | VAF 9/77 reads (12%) | catalogued as COSV60317238; called by muse, mutect2, varscan2
- ZNF534 | c.745C>A p.H249N (on ENST00000332323 / NM_001143939.3; = p.H236N on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56516706; called by muse, mutect2, varscan2
- ABCG2 | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.45); called by muse, mutect2
- ADAM12 | c.933C>A p.F311L | Missense Mutation (SNP) | VAF 48/383 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- APC | c.8411A>T p.Q2804L | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2
- ATP7A | c.2202G>T p.Q734H | Missense Mutation (SNP) | VAF 37/304 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- ATP7A | c.2873T>C p.V958A | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2764A>T p.T922S | Missense Mutation (SNP) | VAF 76/778 reads (10%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BNC2 | c.949A>T p.N317Y | Missense Mutation (SNP) | VAF 47/481 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BOD1L1 | c.4143G>T p.K1381N | Missense Mutation (SNP) | VAF 23/187 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- BRD1 | c.2683T>G p.C895G (on ENST00000216267 / NM_001349940.1; = p.C1026G on NM_001304808.3) | Missense Mutation (SNP) | VAF 43/381 reads (11%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- BRINP3 | c.1674C>G p.C558W | Missense Mutation (SNP) | VAF 55/808 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- C19orf38 | c.98C>A p.P33H | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- C1orf68 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 78/862 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.118); called by muse, mutect2
- CDK3 | c.561G>T p.W187C | Missense Mutation (SNP) | VAF 38/388 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNB4 | c.606C>G p.D202E | Missense Mutation (SNP) | VAF 17/211 reads (8%) | SIFT tolerated (0.36); PolyPhen probably damaging (1); called by muse, mutect2
- CMYA5 | c.2410C>A p.P804T | Missense Mutation (SNP) | VAF 12/212 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- CNBD1 | c.845T>G p.V282G | Missense Mutation (SNP) | VAF 28/249 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); called by muse, mutect2
- COBL | c.2993A>T p.K998M | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- CTSK | c.121-23_121-2del p.X41_splice | Splice Site (DEL) | VAF 30/318 reads (9%) | called by mutect2, pindel
- DRAXIN | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 27/190 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ERC2 | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.983); called by muse, mutect2
- F5 | c.994A>T p.K332* | Nonsense Mutation (SNP) | VAF 45/708 reads (6%) | called by muse, mutect2
- FAM131B | c.98T>C p.M33T | Missense Mutation (SNP) | VAF 93/1040 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.382); called by muse, mutect2
- FBN1 | c.5495G>T p.R1832L | Missense Mutation (SNP) | VAF 118/1391 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- FKBP8 | c.361C>T p.Q121* | Nonsense Mutation (SNP) | VAF 45/365 reads (12%) | called by muse, mutect2, varscan2
- FRMD8 | c.667G>C p.A223P | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.31); called by muse, mutect2
- GJD4 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 26/145 reads (18%) | called by muse, mutect2, varscan2
- GLCE | c.1318G>T p.G440* | Nonsense Mutation (SNP) | VAF 19/163 reads (12%) | called by muse, mutect2, varscan2
- GLG1 | c.2323G>T p.D775Y | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- GLO1 | c.7G>T p.E3* | Nonsense Mutation (SNP) | VAF 20/234 reads (9%) | called by muse, mutect2
- GRID1 | c.2652G>T p.M884I | Missense Mutation (SNP) | VAF 42/351 reads (12%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- HDAC6 | c.1750G>C p.G584R | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HK3 | c.1508A>T p.Q503L | Missense Mutation (SNP) | VAF 27/395 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.028); called by muse, mutect2
- HS6ST2 | c.281G>C p.R94P | Missense Mutation (SNP) | VAF 8/191 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.222); called by muse, mutect2
- KLC3 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 26/234 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- KLF3 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 40/393 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- LAMA2 | c.2822C>A p.A941D | Missense Mutation (SNP) | VAF 101/883 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- LAMP2 | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 102/676 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- LOXHD1 | c.2650G>T p.G884C | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- LOXHD1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, varscan2
- MAD1L1 | c.1675G>T p.E559* | Nonsense Mutation (SNP) | VAF 34/325 reads (10%) | called by muse, mutect2
- ME2 | c.50G>C p.R17P | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- MFSD10 | c.181T>C p.Y61H | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MPPE1 | c.604del p.D202Mfs*20 | Frame Shift Del (DEL) | VAF 32/332 reads (10%) | called by mutect2, pindel, varscan2
- MS4A18 | c.666C>A p.N222K (on ENST00000398983; = p.N224K on NM_001354471.1) | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- MSLNL | c.1032G>T p.L344F | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- MYLPF | c.326C>A p.P109H | Missense Mutation (SNP) | VAF 35/443 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- MYO5B | c.2507G>T p.R836L | Missense Mutation (SNP) | VAF 122/1325 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.018); called by muse, mutect2
- NCALD | c.373G>T p.V125L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, varscan2
- NTN4 | c.1289G>T p.R430L | Missense Mutation (SNP) | VAF 84/758 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2J3 | c.256G>A p.V86I | Missense Mutation (SNP) | VAF 35/248 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR56A5 | c.32C>A p.P11Q | Missense Mutation (SNP) | VAF 17/398 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.429); called by muse, mutect2
- PCDH12 | c.1775T>A p.I592N | Missense Mutation (SNP) | VAF 36/326 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PCDH17 | c.2866C>A p.P956T | Missense Mutation (SNP) | VAF 51/414 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHA1 | c.239A>G p.Q80R | Missense Mutation (SNP) | VAF 111/1164 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2
- PCDHB9 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 95/1126 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2
- PCDHGA8 | c.125G>A p.G42D | Missense Mutation (SNP) | VAF 34/335 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- PCDHGB2 | c.515T>A p.L172H | Missense Mutation (SNP) | VAF 39/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PLAT | c.889T>A p.S297T | Missense Mutation (SNP) | VAF 52/456 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PLCG1 | c.1148C>T p.T383I | Missense Mutation (SNP) | VAF 56/744 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMC6 | c.563G>T p.G188V (on ENST00000612399; = p.G174V on NM_002806.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTPRB | c.1981A>T p.S661C | Missense Mutation (SNP) | VAF 35/301 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- PTPRN | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 18/251 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- QRICH2 | c.4159C>T p.Q1387* | Nonsense Mutation (SNP) | VAF 13/193 reads (7%) | called by muse, mutect2
- RNF103 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 22/220 reads (10%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.987); called by muse, mutect2
- RNF213 | c.556_580del p.T186Rfs*82 | Frame Shift Del (DEL) | VAF 12/125 reads (10%) | called by mutect2, pindel
- ROBO2 | c.1118C>T p.T373I | Missense Mutation (SNP) | VAF 36/384 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); called by muse, mutect2
- RRP12 | c.2230G>A p.A744T | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- SAGE1 | c.2110G>C p.G704R | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- SEMA6D | c.1210C>A p.P404T | Missense Mutation (SNP) | VAF 21/365 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SH2D3A | c.1022A>T p.N341I | Missense Mutation (SNP) | VAF 58/520 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2
- SIGLECL1 | c.293T>C p.L98P | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SIMC1 | c.674C>T p.P225L (on ENST00000443967 / NM_001308196.1; = p.P244L on NM_001308195.2) | Missense Mutation (SNP) | VAF 71/723 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIRPD | c.305C>A p.T102N | Missense Mutation (SNP) | VAF 60/415 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- SLAMF8 | c.643A>G p.T215A | Missense Mutation (SNP) | VAF 22/306 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.6); called by muse, mutect2
- SLC41A2 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SLCO2B1 | c.1262T>A p.V421D | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.088); called by muse, mutect2
- SMOX | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 22/520 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, mutect2
- SPTA1 | c.6480G>T p.Q2160H | Missense Mutation (SNP) | VAF 55/816 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2
- SSC4D | c.268G>T p.V90L | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TAF1L | c.5402del p.G1801Dfs*5 | Frame Shift Del (DEL) | VAF 64/617 reads (10%) | called by mutect2, varscan2
- TENM3 | c.2345C>A p.T782K | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEX11 | c.1144C>A p.L382I (on ENST00000344304; = p.L367I on NM_031276.3) | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.95); called by muse, mutect2
- THTPA | c.499G>T p.E167* | Nonsense Mutation (SNP) | VAF 22/159 reads (14%) | called by muse, mutect2
- TLX3 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 43/476 reads (9%) | called by muse, mutect2
- TMEM229B | c.200T>C p.L67P | Missense Mutation (SNP) | VAF 37/359 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TOP2A | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TRO | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 44/462 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2
- TTN | c.50583G>T p.M16861I (on ENST00000591111; = p.M9437I on NM_003319.4) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TYSND1 | c.330C>A p.C110* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- UNC5C | c.2407G>T p.E803* | Nonsense Mutation (SNP) | VAF 17/141 reads (12%) | called by muse, mutect2, varscan2
- USP51 | c.1673G>T p.R558M | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2
- VPS16 | c.70A>T p.S24C | Missense Mutation (SNP) | VAF 36/467 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2
- VSIG4 | c.317A>T p.D106V | Missense Mutation (SNP) | VAF 40/361 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDR19 | c.1391G>T p.R464L | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- WDR72 | c.2953-2A>T p.X985_splice | Splice Site (SNP) | VAF 26/140 reads (19%) | called by muse, mutect2, varscan2
- ZNF471 | c.854C>A p.T285N | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ANXA9 | c.372A>T p.T124= | Silent (SNP) | VAF 61/609 reads (10%) | called by muse, mutect2, varscan2
- ARHGDIG | c.522C>A p.A174= | Silent (SNP) | VAF 8/53 reads (15%) | called by muse, mutect2, varscan2
- ATCAY | c.234C>A p.S78= | Silent (SNP) | VAF 44/345 reads (13%) | called by muse, mutect2, varscan2
- BRCC3 | c.582C>A p.S194= | Silent (SNP) | VAF 29/335 reads (9%) | called by muse, mutect2
- BTN1A1 | c.1218C>A p.L406= | Silent (SNP) | VAF 28/322 reads (9%) | catalogued as rs770576601, COSV55068391; called by muse, mutect2
- CLIC5 | c.744G>A p.E248= (on ENST00000185206 / NM_001370649.1; = p.E89= on NM_016929.5) | Silent (SNP) | VAF 20/247 reads (8%) | catalogued as COSV99484268; called by muse, mutect2
- COL1A2 | c.4011A>T p.S1337= | Silent (SNP) | VAF 34/335 reads (10%) | catalogued as rs755895022; called by muse, mutect2, varscan2
- CSMD1 | c.6306G>T p.S2102= (on ENST00000520002; = p.S2101= on NM_033225.6) | Silent (SNP) | VAF 40/506 reads (8%) | catalogued as COSV59349074; called by muse, mutect2
- CSMD2 | c.5661C>T p.Y1887= | Silent (SNP) | VAF 26/312 reads (8%) | called by muse, mutect2
- CYP7B1 | c.1296G>T p.G432= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as COSV59592573; called by muse, mutect2, varscan2
- DNAH11 | c.10422C>G p.P3474= | Silent (SNP) | VAF 36/328 reads (11%) | called by muse, mutect2, varscan2
- EML2 | c.153G>C p.S51= | Silent (SNP) | VAF 32/308 reads (10%) | catalogued as rs1291435978; called by muse, mutect2, varscan2
- ERI3 | c.918C>A p.P306= | Silent (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- EVPL | c.900G>T p.A300= | Silent (SNP) | VAF 40/361 reads (11%) | called by mutect2, varscan2
- FHAD1 | c.2493A>G p.K831= | Silent (SNP) | VAF 36/288 reads (13%) | catalogued as rs761823036; called by muse, mutect2, varscan2
- GABRG2 | c.84G>T p.L28= | Silent (SNP) | VAF 116/934 reads (12%) | called by muse, mutect2, varscan2
- GRAMD1C | c.429C>T p.N143= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs368678833, COSV63982673; called by mutect2, varscan2
- GRHL1 | c.843C>T p.P281= | Silent (SNP) | VAF 16/311 reads (5%) | called by muse, mutect2
- HS3ST2 | c.144C>A p.R48= | Silent (SNP) | VAF 41/409 reads (10%) | called by muse, mutect2
- JMJD1C | c.2802G>T p.R934= | Silent (SNP) | VAF 27/272 reads (10%) | called by muse, mutect2
- KRT31 | c.843C>A p.A281= | Silent (SNP) | VAF 59/645 reads (9%) | catalogued as rs1567681883; called by muse, mutect2
- KRT79 | c.1251G>A p.Q417= | Silent (SNP) | VAF 83/708 reads (12%) | catalogued as rs1203900780, COSV57942646; called by muse, mutect2, varscan2
- LCE1C | c.42C>A p.P14= | Silent (SNP) | VAF 38/361 reads (11%) | catalogued as COSV100908458; called by muse, mutect2
- MC2R | c.81G>A p.P27= | Silent (SNP) | VAF 30/296 reads (10%) | catalogued as rs774058197, COSV59617029; called by muse, mutect2
- MPP2 | c.582G>A p.G194= (on ENST00000461854 / NM_001278372.2; = p.G170= on NM_005374.5) | Silent (SNP) | VAF 42/475 reads (9%) | called by muse, mutect2
- MYO7B | c.4228C>A p.R1410= | Silent (SNP) | VAF 43/384 reads (11%) | catalogued as COSV101267962; called by mutect2, varscan2
- NLRP1 | c.1587C>T p.C529= | Silent (SNP) | VAF 40/452 reads (9%) | called by muse, mutect2
- OR52E8 | c.480C>T p.Y160= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- OR5T2 | c.669C>G p.L223= | Silent (SNP) | VAF 14/73 reads (19%) | catalogued as rs551957231, COSV100506831; called by muse, mutect2, varscan2
- OR8J3 | c.78C>A p.P26= | Silent (SNP) | VAF 50/305 reads (16%) | called by muse, mutect2, varscan2
- OR9G1 | c.387G>C p.L129= | Silent (SNP) | VAF 50/638 reads (8%) | called by muse, mutect2
- PER1 | c.2109G>C p.L703= | Silent (SNP) | VAF 16/210 reads (8%) | called by muse, mutect2
- PMP2 | c.24C>A p.T8= | Silent (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- PRKCG | c.366C>T p.Y122= | Silent (SNP) | VAF 54/545 reads (10%) | called by muse, mutect2
- SH3BGRL | c.300A>T p.P100= | Silent (SNP) | VAF 34/357 reads (10%) | called by muse, mutect2
- SPG11 | c.3154C>T p.L1052= | Silent (SNP) | VAF 89/922 reads (10%) | called by muse, mutect2
- TENT5D | c.402G>A p.L134= | Silent (SNP) | VAF 19/227 reads (8%) | called by muse, mutect2
- TFDP3 | c.933C>T p.A311= | Silent (SNP) | VAF 34/498 reads (7%) | catalogued as COSV59538268; called by muse, mutect2
- TMEM255B | c.729C>T p.P243= | Silent (SNP) | VAF 36/344 reads (10%) | catalogued as rs377230958; called by muse, mutect2
- TMEM63B | c.1743C>T p.N581= | Silent (SNP) | VAF 16/238 reads (7%) | catalogued as rs1454287466; called by muse, mutect2
- TPO | c.1254C>A p.A418= | Silent (SNP) | VAF 34/427 reads (8%) | catalogued as rs1443612056; called by muse, mutect2
- UAP1 | c.198T>C p.D66= | Silent (SNP) | VAF 46/628 reads (7%) | catalogued as rs748085639; called by muse, mutect2
- UGT2B4 | c.777A>G p.R259= | Silent (SNP) | VAF 25/172 reads (15%) | called by muse, mutect2, varscan2
- WDR90 | c.4545G>T p.T1515= | Silent (SNP) | VAF 16/202 reads (8%) | called by muse, mutect2
- YIF1B | c.198C>A p.P66= (on ENST00000339413 / NM_001039673.3; = p.P51= on NM_001039671.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/410 reads (10%) | called by muse, mutect2, varscan2
- ZNF467 | c.510G>A p.R170= | Silent (SNP) | VAF 31/302 reads (10%) | called by muse, mutect2
- ZNF862 | c.828A>G p.A276= | Silent (SNP) | VAF 18/311 reads (6%) | called by muse, mutect2
- AC136759.1 | n.1149A>T | RNA (SNP) | VAF 128/890 reads (14%) | called by muse, mutect2
- BAALC-AS2 | n.390G>T | RNA (SNP) | VAF 22/208 reads (11%) | called by muse, mutect2, varscan2
- C19orf25 | c.*123C>T | 3'UTR (SNP) | VAF 9/52 reads (17%) | catalogued as rs574096946; called by muse, mutect2, varscan2
- CCDC33 | c.1291-11560G>T | Intron (SNP) | VAF 29/243 reads (12%) | called by muse, mutect2, varscan2
- CNKSR2 | c.228+41del | Intron (DEL) | VAF 20/126 reads (16%) | called by mutect2, pindel, varscan2
- GVINP1 | n.3540C>G | RNA (SNP) | VAF 23/256 reads (9%) | called by muse, mutect2
- HSPD1 | c.510+23G>T | Intron (SNP) | VAF 25/155 reads (16%) | catalogued as rs775517521; called by muse, mutect2, varscan2
- IGSF9 | c.1246-34G>C | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- IL13RA1 | c.1010-3311C>G | Intron (SNP) | VAF 40/418 reads (10%) | called by muse, mutect2, varscan2
- JPT1 | c.57-464C>T | Intron (SNP) | VAF 32/224 reads (14%) | called by muse, mutect2, varscan2
- LINC01098 | n.817G>C | RNA (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- MACF1 | c.13228+26G>T | Intron (SNP) | VAF 35/378 reads (9%) | called by muse, mutect2
- MZB1 | c.177+266C>T | Intron (SNP) | VAF 26/328 reads (8%) | called by muse, mutect2
- NEU4 | c.-4+145G>T | Intron (SNP) | VAF 18/142 reads (13%) | called by muse, mutect2, varscan2
- NRXN1 | c.3365-109832G>T | Intron (SNP) | VAF 70/744 reads (9%) | called by muse, mutect2
- OR7E5P | n.127T>A | RNA (SNP) | VAF 51/302 reads (17%) | called by muse, mutect2, varscan2
- PFKFB4 | c.97+509A>T | Intron (SNP) | VAF 68/692 reads (10%) | called by muse, mutect2
- PIPSL | n.2296G>A | RNA (SNP) | VAF 44/364 reads (12%) | catalogued as rs1429338772; called by muse, mutect2, varscan2
- PRKCG | c.*8C>G | 3'UTR (SNP) | VAF 37/310 reads (12%) | catalogued as rs778633577; called by muse, mutect2, varscan2
- RHAG | c.*1C>A | 3'UTR (SNP) | VAF 50/522 reads (10%) | called by muse, mutect2
- RUNX2 | chr6:45328354 A>G | 5'Flank (SNP) | VAF 38/285 reads (13%) | called by muse, mutect2, varscan2
- SLC35E2B | c.*31C>A | 3'UTR (SNP) | VAF 15/111 reads (14%) | called by mutect2, varscan2
- SNTG2 | c.325+4998G>C | Intron (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- TFB1M | c.-7G>T | 5'UTR (SNP) | VAF 118/1155 reads (10%) | catalogued as rs982033469; called by muse, mutect2, varscan2
- THSD4 | c.-80+15132G>T | Intron (SNP) | VAF 29/251 reads (12%) | called by muse, mutect2, varscan2
- ZBP1 | c.1094-2361G>C | Intron (SNP) | VAF 20/226 reads (9%) | catalogued as rs932738780; called by muse, mutect2
- ZEB2 | c.73+4069G>T | Intron (SNP) | VAF 31/230 reads (13%) | called by muse, mutect2, varscan2
